Somatic mutation profile of tumor specimen 0DBD0U from CCDI case PBBKZS, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Dysembryoplastic neuroepithelial tumor; Tissue or organ of origin: Temporal lobe; Age at diagnosis: 9.7 years (3,553 days).
Specimen 0DBD0U: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0d67ba2d-d4b6-4db6-ace3-fafc86c5af14.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DBD0V (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3186682a-57c4-4d2c-97ea-aef6481b2ac8

The open-access MAF lists 8 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR1 | c.1636A>G p.N546D (on ENST00000447712 / NM_023110.3; = p.N544D on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 172/593 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519898, COSV58330676; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 375/1104 reads (34%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CD1E | c.793G>A p.E265K | Missense Mutation (SNP) | VAF 153/456 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.043); catalogued as rs754722731, COSV63771196; called by muse, mutect2, varscan2
- FGFR1 | c.1955A>G p.D652G (on ENST00000447712 / NM_023110.3; = p.D650G on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 277/910 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58327169; called by muse, mutect2, varscan2
- GAS8 | c.55G>A p.D19N | Missense Mutation (SNP) | VAF 341/1040 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs781205439, COSV99244254; called by muse, mutect2, varscan2
- LAMA3 | c.4157G>A p.G1386E | Missense Mutation (SNP) | VAF 291/870 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCSK5 | c.2726C>A p.T909K | Missense Mutation (SNP) | VAF 130/505 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.8); called by muse, mutect2, varscan2
- METRN | c.-100C>T | 5'UTR (SNP) | VAF 6/10 reads (60%) | called by mutect2, varscan2
